Somatic mutation profile of tumor specimen 0DNMB7 from CCDI case PBCBYX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 8.7 years (3,174 days).
Specimen 0DNMB7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5b2749d9-b473-4239-9869-5b12695f042e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DNMA6 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/79d054e6-317d-44ed-9680-c7836ddaeb39

The open-access MAF lists 11 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 2, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS5 | c.2054C>A p.T685N | Missense Mutation (SNP) | VAF 180/614 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.299); catalogued as COSV53178917; called by muse, mutect2
- CNKSR1 | c.1088G>T p.G363V (on ENST00000374253 / NM_001297647.2; = p.G356V on NM_006314.3) | Missense Mutation (SNP) | VAF 356/781 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.221); catalogued as COSV64162957; called by muse, mutect2, varscan2
- IQGAP1 | c.3952C>T p.P1318S | Missense Mutation (SNP) | VAF 89/370 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.157); catalogued as COSV99184959; called by muse, mutect2, varscan2
- SAFB2 | c.2093G>A p.R698H | Missense Mutation (SNP) | VAF 191/415 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs747283758, COSV53042677; called by muse, mutect2, varscan2
- TMEM131 | c.4786C>T p.R1596C | Missense Mutation (SNP) | VAF 62/1256 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.732); catalogued as rs745591248; called by muse, mutect2
- EYA2 | c.623C>T p.S208F | Missense Mutation (SNP) | VAF 171/844 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- ZNF510 | c.742C>G p.Q248E | Missense Mutation (SNP) | VAF 33/988 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2
- USP37 | c.2937G>A p.L979= | Silent (SNP) | VAF 163/396 reads (41%) | catalogued as rs757511411; called by muse, mutect2, varscan2
- WBP2NL | c.255T>A p.V85= | Silent (SNP) | VAF 50/899 reads (6%) | called by muse, mutect2
- ACHE | c.1723+182C>T | Intron (SNP) | VAF 54/462 reads (12%) | called by muse, mutect2, varscan2
- ME2 | c.393-86T>A | Intron (SNP) | VAF 8/66 reads (12%) | called by muse, varscan2
